Gene-level copy-number profile of tumor specimen TCGA-CC-A3M9-01A from TCGA case TCGA-CC-A3M9, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, spindle cell variant; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 45.1 years (16,460 days).
Specimen TCGA-CC-A3M9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.7528ae95-b07c-4937-804a-7280ce786d5f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CC-A3M9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f24971de-91b8-430a-ba6b-40012bdcc1da

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 105; copy number 2: 1,573; copy number 3: 4,618; copy number 4: 18,628; copy number 5: 10,692; copy number 6: 8,959; copy number 7: 5,186; copy number 8: 5,442; copy number 9: 3,599; copy number 10: 553; copy number 11: 51; copy number 12: 269; copy number 13: 36; copy number 19: 34; copy number 21: 19; copy number 25: 22; copy number 50: 16; copy number 96: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CC-A3M9-01A-11D-A20V-01): tumor purity 0.3, ploidy 2.7, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 4,603 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:197,902,630–201,584,367, 66 genes, copy number 13–19 (within-gene range 6–19) (broad region; genes not listed).
- chr2:120,464,335–122,887,691, 26 genes, copy number 10 (within-gene range 8–10): LINC01101, AC073257.2, AC073257.1, Y_RNA, AC018866.1, GLI2, AC017033.1, Y_RNA, AC067960.1, AC079988.1, TFCP2L1, RPS17P7, CLASP1, AC012447.1, RNU4ATAC, Y_RNA, NIFK-AS1, RPL12P15, AC018737.2, NPM1P32, NIFK, TSN, AC018737.1, LINC01823, AC011246.1, AC073632.1.
- chr3:104,063,039–105,869,552, 4 genes, copy number 11 (within-gene range 5–11): RAP1BP2, AC091804.1, ALCAM, CBLB.
- chr5:58,198–1,295,068, 47 genes, copy number 11: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT.
- chr6:47,781,982–50,857,662, 39 genes, copy number 9–10 (within-gene range 4–10): OPN5, RNU1-105P, PTCHD4, AL353138.1, HNRNPA3P4, RBMXP1, FO393412.1, AL391538.1, AL022099.1, AL589994.1, AL589994.2, FO393413.1, RNU7-65P, EEF1A1P42, MMUT, CENPQ, GLYATL3, C6orf141, CYP2AC1P, RHAG, CRISP2, AL121974.1, AL121950.1, CRISP3, PGK2, AL359458.1, CRISP1, DEFB133, DEFB114, DEFB113, DEFB110, DEFB112, AL138826.1, AL132799.1, AL360175.1, AL135908.1, TFAP2D, TFAP2B, RPS17P5.
- chr7:110,590,082–110,592,204, 1 gene, copy number 10: AC073326.2.
- chr7:110,724,159–110,725,825, 1 gene, copy number 10: AC073326.1.
- chr8:35,235,475–49,907,446, 263 genes, copy number 9–12 (broad region; genes not listed).
- chr8:62,658,343–64,369,176, 21 genes, copy number 12 (within-gene range 8–12): AC090577.1, XRCC6P4, SRPK2P, AC120042.1, GGH, AC120042.2, TTPA, AC011978.1, YTHDF3-AS1, YTHDF3, AC011978.2, RN7SL135P, AC011124.1, IFITM8P, AC011124.2, AC018953.1, RN7SKP135, AC018953.2, LINC01414, AC069133.1, LINC01289.
- chr10:34,488,583–35,800,920, 29 genes, copy number 12–13: ELOBP4, RPL37P18, RPS12P16, PARD3-AS1, SS18L2P1, RNU6-847P, RNU6-193P, PRDX2P2, LINC02635, CUL2, MIR3611, AL392046.1, CREM, RNU7-77P, ATP6V1G1P4, AL117336.1, LINC02634, RNU6-794P, CCNY, RNU6-1167P, AL117336.2, AL603824.1, AL121749.1, GJD4, FZD8, AL121749.2, MIR4683, RPL7P37, PCAT5.
- chr11:55,279,447–55,858,547, 37 genes, copy number 10 (within-gene range 7–10): AP005597.3, AP005597.2, TRIM51HP, AP005597.1, OR4A11P, OR4A12P, OR4A16, OR4A15, OR4A9P, OR4X7P, OR4A10P, OR4A17P, OR4A13P, OR4A50P, OR4A21P, OR4C1P, OR4C14P, OR4C15, OR4C16, OR4C11, OR4P4, OR4S2, OR4C6, OR4V1P, OR4P1P, AP006437.1, OR5D2P, OR5D3P, OR5D17P, OR5D13, OR5D15P, OR5D14, OR5L1, OR5D18, OR5L2, OR5D16, OR9M1P.
- chr11:55,865,709–55,865,820, 1 gene, copy number 10: AC036111.3.
- chr11:69,000,765–70,207,390, 37 genes, copy number 21–96: AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1.
- chr11:70,278,921–70,279,297, 1 gene, copy number 50: H2AZP4.
- chr11:70,283,955–70,284,070, 1 gene, copy number 50: MIR548K.
- chr12:102,304,355–102,513,655, 3 genes, copy number 9 (within-gene range 4–9): LINC02456, IGF1, AC010202.1.
- chr14:24,399,003–106,875,071, 1,823 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr15:95,186,634–101,933,350, 155 genes, copy number 12 (broad region; genes not listed).
- chr17:3,714,628–16,569,204, 455 genes, copy number 10 (broad region; genes not listed).
- chr17:26,981,694–30,469,989, 187 genes, copy number 9–25 (within-gene range 5–25) (broad region; genes not listed).
- chr20:25,985,210–64,313,132, 929 genes, copy number 9 (broad region; genes not listed).
- chr22:15,290,718–23,328,493, 477 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 105. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
